Somatic mutation profile of tumor specimen TCGA-EJ-AB20-01A (aliquot TCGA-EJ-AB20-01A-12D-A41K-08) from TCGA case TCGA-EJ-AB20, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.9 years (22,626 days).
Specimen TCGA-EJ-AB20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1279a1fc-ed25-4c7f-a88b-4cf29ad53815.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-AB20-10A (Blood Derived Normal), aliquot TCGA-EJ-AB20-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab81ac15-3928-48a1-8387-3c9b599e6574

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100304372, COSV100304621; called by muse, mutect2, varscan2
- ARHGEF26 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1325869647, COSV62850539; called by muse, mutect2
- AXDND1 | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.997); catalogued as COSV100858587; called by muse, mutect2
- FYN | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99992311; called by muse, mutect2, varscan2
- NDST1 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs150009231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUMA1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs766430228, COSV100706507; called by muse, mutect2
- PLPPR4 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as rs759132918, COSV100926889, COSV64567601; called by muse, mutect2, varscan2
- QRICH1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.238); catalogued as COSV100676943; called by muse, mutect2, varscan2
- ZNF699 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100427064; called by muse, mutect2, varscan2
- SLC35G5 | c.802_806del p.T268Cfs*34 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- MS4A13 | c.18C>T p.H6= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1164234807, COSV100981181, COSV65445356; called by muse, mutect2, varscan2
- SORBS2 | c.1092C>T p.N364= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs772180081, COSV52999965; called by muse, mutect2, varscan2
- VWA8 | c.4365C>G p.V1455= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101022879, COSV64998256; called by muse, mutect2
